CCDI case PBCFUR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9323723c-14b9-4a3f-a00f-98da843758c5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.0 years (5,465 days).

Biospecimens (3 samples)
- Sample 0DQZ3L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQZ3R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQZ4V: Tissue type: Tumor; Specimen type: Solid Tissue.
